MMRF case MMRF_2268 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/495ed739-8eda-41a3-ad63-45bf76568094

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.1 years (26,685 days); ISS stage: II; Days to last known disease status: 802 days (2.2 years); Days to last follow up: 802 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 405 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 92 days; Days to treatment end: 405 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 3.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.602 mg/dL; Immunoglobulin G 54.2 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.276 g/L; Beta 2 Microglobulin 4.29 µg/mL; Lactate Dehydrogenase 1.38 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 11.1 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 658 ×10⁹/L; Creatinine 75 µmol/L; Calcium 2.59 mmol/L; Albumin 33.2 g/L; Total Protein 10.2 g/dL; Glucose 6.3 mmol/L; C-Reactive Protein 7.07 mg/dL.
- Day 88 (ECOG 0): M Protein 1.2 g/dL; Immunoglobulin G 24.2 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.309 g/L; Beta 2 Microglobulin 3.16 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.44 ×10⁹/L; Absolute Neutrophil 4.37 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 68 µmol/L; Blood Urea Nitrogen 5.21 mmol/L; Calcium 2.39 mmol/L; Albumin 40.5 g/L; Total Protein 8.01 g/dL; Glucose 5.2 mmol/L.
- Day 172 (ECOG 0): M Protein 8.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.957 mg/dL; Immunoglobulin G 19.1 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 3.53 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.35 ×10⁹/L; Absolute Neutrophil 4.51 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 71 µmol/L; Blood Urea Nitrogen 5.8 mmol/L; Calcium 2.45 mmol/L; Albumin 43.3 g/L; Total Protein 7.84 g/dL; Glucose 6.1 mmol/L.
- Day 257 (ECOG 0): M Protein 5.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 2.15 g/L; Immunoglobulin M 0.262 g/L; Beta 2 Microglobulin 2.84 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.39 ×10⁹/L; Absolute Neutrophil 4.64 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.45 mmol/L; Albumin 44.1 g/L; Total Protein 7.52 g/dL; Glucose 6.6 mmol/L.
- Day 340 (ECOG 0): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.602 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 2.15 g/L; Immunoglobulin M 0.229 g/L; Beta 2 Microglobulin 2.43 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.72 ×10⁹/L; Absolute Neutrophil 4.85 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 77 µmol/L; Calcium 2.44 mmol/L; Albumin 43.4 g/L; Total Protein 7.18 g/dL; Glucose 5.9 mmol/L.
- Day 445 (ECOG 0): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 2.42 g/L; Immunoglobulin M 0.317 g/L; Beta 2 Microglobulin 2.82 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 78 µmol/L; Blood Urea Nitrogen 5.6 mmol/L; Calcium 2.42 mmol/L; Albumin 43.6 g/L; Total Protein 7.26 g/dL; Glucose 6.9 mmol/L.
- Day 540 (ECOG 0): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.968 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 3.07 g/L; Immunoglobulin M 0.481 g/L; Beta 2 Microglobulin 2.32 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 338 ×10⁹/L; Creatinine 83 µmol/L; Blood Urea Nitrogen 4.2 mmol/L; Calcium 2.41 mmol/L; Albumin 45.6 g/L; Total Protein 7.48 g/dL; Glucose 7.2 mmol/L.
- Day 628 (ECOG 0): M Protein 0.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 16.4 g/L; Immunoglobulin A 2.86 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 86 µmol/L; Calcium 2.39 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 8.3 mmol/L.
- Day 718 (ECOG 0): M Protein 1.03 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 21.8 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.361 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 8.5 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 74 µmol/L; Blood Urea Nitrogen 5.3 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 8.2 g/dL; Glucose 8.7 mmol/L.
- Day 802 (ECOG 0): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 32 g/L; Immunoglobulin A 2.32 g/L; Immunoglobulin M 0.312 g/L; Beta 2 Microglobulin 3.57 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 80 µmol/L; Calcium 2.47 mmol/L; Albumin 42.2 g/L; Total Protein 8.64 g/dL; Glucose 6.8 mmol/L.

Other clinical attributes
- Day -10: Weight: 70 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2268_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2268_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
